CCDI case PBCBEA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/c32760ca-aa8a-45e6-b572-9bcf72f5ea99

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Atypical teratoid/rhabdoid tumor: ICD-O-3 morphology code: 9508/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 12.9 years (4,705 days).

Biospecimens (3 samples)
- Sample 0DN1BB: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DN1BZ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DN1DG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
